Somatic mutation profile of tumor specimen TCGA-UF-A7JT-01A (aliquot TCGA-UF-A7JT-01A-11D-A34J-08) from TCGA case TCGA-UF-A7JT, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 72.2 years (26,375 days).
Specimen TCGA-UF-A7JT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b12b973-41e1-439b-944d-69671858d0dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UF-A7JT-10A (Blood Derived Normal), aliquot TCGA-UF-A7JT-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/053adb6d-83a5-4213-a4e9-869c8975d52c

The open-access MAF lists 224 somatic variants for this specimen: 167 protein-altering or splice-affecting, 53 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 146, Silent 53, Nonsense Mutation 10, Splice Site 4, Frame Shift Del 4, Intron 2, In Frame Del 2, RNA 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 5/24 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2
- ACTA2 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV56517619; called by muse, mutect2, varscan2
- ADI1 | c.377C>T p.T126M | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs752197674, COSV59377810; called by muse, mutect2, varscan2
- AGO2 | c.1424G>A p.R475K | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as COSV99596295; called by muse, mutect2, varscan2
- AHNAK | c.4035G>C p.L1345F | Missense Mutation (SNP) | VAF 32/356 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV99949313; called by muse, mutect2
- AK5 | c.601G>C p.E201Q (on ENST00000354567 / NM_174858.3; = p.E175Q on NM_012093.4) | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.84); catalogued as COSV100481480, COSV100481565; called by muse, mutect2, varscan2
- AKAP13 | c.7963C>T p.R2655C (on ENST00000394518 / NM_007200.5; = p.R2659C on NM_006738.6) | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1448656405, COSV63465796; called by muse, mutect2, varscan2
- AKAP5 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100278073, COSV57742507; called by muse, mutect2, varscan2
- ALDH8A1 | c.11C>T p.T4I | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.044); catalogued as COSV99664976; called by muse, mutect2, varscan2
- ALPK1 | c.784C>G p.Q262E | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV99455065; called by mutect2, varscan2
- AMOT | c.1369G>C p.E457Q (on ENST00000371959 / NM_001113490.1; = p.E48Q on NM_133265.3) | Missense Mutation (SNP) | VAF 75/369 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.655); catalogued as COSV100495484; called by muse, mutect2, varscan2
- APC | c.5779C>T p.L1927F | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs730881253, COSV99969848; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARFGEF1 | c.3850C>G p.L1284V | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.489); catalogued as rs1410248694, COSV99144278; called by muse, mutect2, varscan2
- ARNT | c.38A>G p.D13G | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as COSV100591344; called by muse, mutect2, varscan2
- ATP11B | c.421C>T p.R141W | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs1287322718, COSV60026891; called by muse, mutect2, varscan2
- ATR | c.737C>T p.S246F | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.118); catalogued as COSV100638537; called by muse, mutect2, varscan2
- BAHCC1 | c.5599G>C p.E1867Q | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.034); catalogued as COSV100311993; called by muse, mutect2
- BCORL1 | c.3422G>A p.R1141Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.047); catalogued as rs1238653823, COSV99498655; called by muse, mutect2
- BMS1 | c.3235G>A p.E1079K | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.176); catalogued as COSV65736004; called by muse, mutect2, varscan2
- BYSL | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.145); catalogued as COSV100026933, COSV57829618; called by muse, mutect2, varscan2
- C11orf87 | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs769535254, COSV59356166; called by muse, mutect2, varscan2
- CADPS2 | c.839G>T p.R280L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100465542, COSV57387911; called by muse, mutect2, varscan2
- CAMSAP2 | c.3034C>T p.L1012F (on ENST00000236925 / NM_001297707.2; = p.L1001F on NM_203459.3) | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs756195287, COSV99374200; called by muse, mutect2, varscan2
- CAPN6 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0.221); catalogued as COSV100137041; called by muse, mutect2
- CCNB3 | c.2563C>G p.H855D | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.088); catalogued as COSV99329714; called by muse, mutect2, varscan2
- CCR9 | c.938A>G p.N313S (on ENST00000357632 / NM_031200.3; = p.N301S on NM_006641.4) | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100591767; called by muse, mutect2, varscan2
- CD247 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV100758467, COSV62978334; called by muse, mutect2, varscan2
- CEP126 | c.624G>T p.L208F | Missense Mutation (SNP) | VAF 38/225 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV54825879; called by muse, mutect2, varscan2
- CES3 | c.1360G>C p.A454P | Missense Mutation (SNP) | VAF 53/275 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs762922918, COSV100310034, COSV57595058; called by muse, mutect2, varscan2
- CHD6 | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.342); catalogued as COSV100498040, COSV100498622; called by muse, mutect2, varscan2
- CPT2 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1131691925, CM030819, COSV99598308; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPT2 | c.763G>C p.D255H | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771250137, COSV99598310; called by muse, mutect2, varscan2
- DCLK2 | c.785A>G p.D262G | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV99652649; called by muse, mutect2, varscan2
- DGKA | c.1840G>A p.D614N | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as rs1565766882, COSV100093370; called by muse, mutect2
- DNAH2 | c.508G>T p.A170S | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.005); catalogued as COSV99318508; called by muse, mutect2, varscan2
- DNAJC14 | c.934G>A p.G312R | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.209); catalogued as rs1172996632, COSV100423700; called by muse, mutect2, varscan2
- DOCK9 | c.622G>A p.D208N (on ENST00000376460 / NM_001366676.2; = p.D209N on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100240802; called by muse, mutect2, varscan2
- DPP10 | c.1876G>C p.D626H | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100071087; called by muse, mutect2, varscan2
- DUS2 | c.753C>G p.I251M | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV100732652; called by muse, mutect2, varscan2
- DYSF | c.5042C>T p.P1681L | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99250092; called by muse, mutect2, varscan2
- EIF4G3 | c.2428G>A p.A810T | Missense Mutation (SNP) | VAF 18/185 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs1215059821, COSV99945413; called by muse, mutect2
- ELAVL1 | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100688491; called by muse, mutect2, varscan2
- ELP1 | c.1723G>A p.D575N | Missense Mutation (SNP) | VAF 45/203 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.217); catalogued as COSV101010467; called by muse, mutect2, varscan2
- EMSY | c.3253G>A p.E1085K | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.395); catalogued as COSV100596020; called by muse, mutect2
- FBXW10 | c.2327G>A p.R776Q | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs375352795; called by muse, mutect2, varscan2
- FSTL5 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.15); catalogued as COSV100060349, COSV60187089; called by muse, mutect2, varscan2
- FZR1 | c.1360G>A p.D454N | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV58053221; called by muse, mutect2, varscan2
- GABRP | c.979G>T p.A327S | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as COSV99517064; called by muse, mutect2, varscan2
- GADD45A | c.154G>C p.D52H | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV100921474; called by muse, mutect2
- GCC1 | c.268C>G p.H90D | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99133908; called by muse, mutect2
- GDAP2 | c.535G>C p.E179Q | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.812); catalogued as COSV101032149; called by muse, varscan2
- GDAP2 | c.472G>C p.E158Q | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101032151; called by muse, varscan2
- GFPT2 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.693); catalogued as rs760185269, COSV53809471; called by muse, mutect2, varscan2
- GGCX | c.1435C>A p.Q479K | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV99290162; called by muse, mutect2, varscan2
- GHR | c.298G>C p.E100Q | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100051881, COSV50131388; called by muse, mutect2, varscan2
- GIMAP1 | c.15G>C p.K5N | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV100212281; called by muse, mutect2, varscan2
- GMPS | c.905C>G p.S302C | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs1339812781, COSV55810377, COSV99903351; called by muse, mutect2, varscan2
- GOLGA3 | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); catalogued as COSV99212524; called by muse, mutect2, varscan2
- GRIP1 | c.171G>A p.M57I | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99670787; called by muse, mutect2, varscan2
- HAS2 | c.73G>T p.G25* | Nonsense Mutation (SNP) | VAF 43/107 reads (40%) | catalogued as COSV100392136; called by muse, mutect2, varscan2
- HEATR6 | c.3257C>T p.S1086L | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.089); catalogued as rs533357378, COSV99482490; called by muse, mutect2, varscan2
- HERC2 | c.3757G>T p.A1253S | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.34); catalogued as rs753357781, COSV99876425; called by muse, mutect2, varscan2
- HLA-A | c.236A>G p.E79G | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100954657; called by muse, mutect2, varscan2
- HLA-A | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs41543413, COSV65144602; called by muse, varscan2
- HLA-B | c.748C>T p.Q250* | Nonsense Mutation (SNP) | VAF 28/123 reads (23%) | catalogued as COSV69522776, COSV69523296; called by muse, mutect2, varscan2
- HSP90AB1 | c.2092G>C p.E698Q | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.435); catalogued as COSV99241380; called by muse, mutect2, varscan2
- HSPG2 | c.9765G>T p.Q3255H | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as COSV101013550; called by muse, mutect2, varscan2
- HUWE1 | c.9964G>A p.V3322I | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.854); catalogued as rs782714213, COSV53334510; called by muse, mutect2
- IL10RA | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.731); catalogued as COSV57141458; called by muse, mutect2, varscan2
- INKA1 | c.151T>G p.S51A | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as COSV100323740; called by muse, mutect2, varscan2
- INPP5E | c.1411G>T p.E471* | Nonsense Mutation (SNP) | VAF 9/90 reads (10%) | catalogued as COSV100867270; called by muse, mutect2, varscan2
- IQCB1 | c.984C>G p.F328L | Missense Mutation (SNP) | VAF 37/182 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100182101; called by muse, mutect2, varscan2
- IQSEC1 | c.487G>C p.E163Q | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1316276894, COSV99832284; called by muse, mutect2, varscan2
- JADE3 | c.147C>G p.I49M | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99510231; called by muse, mutect2, varscan2
- JCAD | c.1445C>A p.P482H | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as rs767367414, COSV100948542; called by muse, mutect2, varscan2
- KAT6A | c.2142G>C p.K714N | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV99705764; called by muse, mutect2, varscan2
- KBTBD4 | c.894G>A p.M298I | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.535); catalogued as COSV100442947; called by muse, mutect2, varscan2
- KCNB2 | c.2234C>T p.S745L | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs557129070, COSV73052458; called by muse, mutect2, varscan2
- KCNJ10 | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs751338154, COSV63633400, COSV63634235; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KEAP1 | c.1275C>G p.I425M | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.809); catalogued as rs754011905, COSV50270837; called by muse, mutect2, varscan2
- KHDRBS2 | c.176A>G p.K59R | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.571); catalogued as COSV99836985; called by muse, mutect2, varscan2
- KHSRP | c.1193C>G p.P398R | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as COSV101231243; called by muse, mutect2, varscan2
- KIAA1549 | c.1019G>C p.R340T | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as COSV54313161, COSV99651799; called by muse, mutect2, varscan2
- KLF8 | c.1012G>C p.D338H | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.924); catalogued as COSV100808399; called by muse, mutect2, varscan2
- KMT2D | c.11230C>T p.Q3744* | Nonsense Mutation (SNP) | VAF 4/19 reads (21%) | catalogued as COSV99985372; called by muse, mutect2
- KRT3 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100527283; called by muse, mutect2
- LAMA4 | c.773_775del p.E258del | In Frame Del (DEL) | VAF 20/82 reads (24%) | catalogued as rs782474127; called by pindel, varscan2
- LARP4 | c.399-1G>C p.X133_splice | Splice Site (SNP) | VAF 12/44 reads (27%) | catalogued as COSV99529594; called by mutect2, varscan2
- LRP10 | c.1748C>T p.T583I | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as rs767418731, COSV100612486; called by muse, mutect2, varscan2
- LRRC7 | c.565G>C p.E189Q (on ENST00000651989 / NM_001370785.2; = p.E156Q on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.933); catalogued as COSV50417577, COSV99229386; called by muse, mutect2, varscan2
- LRTOMT | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.059); catalogued as COSV99194450; called by muse, mutect2, varscan2
- MAP1B | c.1947G>T p.K649N | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.102); catalogued as COSV99702884; called by muse, mutect2, varscan2
- MON1B | c.641A>C p.Q214P | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.783); catalogued as COSV99941836; called by muse, mutect2, varscan2
- MON1B | c.642G>T p.Q214H | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs777592808, COSV99941837; called by muse, mutect2, varscan2
- MROH8 | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.08); catalogued as rs994509871, COSV54120202; called by muse, mutect2, varscan2
- MRPL43 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.046); catalogued as COSV99273138; called by muse, mutect2
- MYL3 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs758048820, COSV52767718; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NAV1 | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1251917825, COSV99819567; called by muse, mutect2, varscan2
- NEDD4 | c.3664C>G p.Q1222E (on ENST00000508342 / NM_001284338.1; = p.Q803E on NM_006154.4) | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.414); catalogued as COSV100164055; called by muse, mutect2, varscan2
- NETO1 | c.1213G>T p.A405S | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.083); catalogued as COSV100199617; called by muse, mutect2, varscan2
- NIBAN2 | c.1340C>T p.T447M | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780212910, COSV64824372; called by muse, mutect2, varscan2
- NINJ2 | c.354C>G p.I118M | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV99843510; called by muse, mutect2, varscan2
- NLRP3 | c.2601C>A p.D867E | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.296); catalogued as COSV100276557; called by muse, mutect2, varscan2
- OPLAH | c.947G>A p.G316E | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554759895, COSV101470906; called by muse, mutect2, varscan2
- OR13F1 | c.503T>A p.L168H | Missense Mutation (SNP) | VAF 41/176 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100594839; called by muse, mutect2, varscan2
- P2RY8 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); catalogued as rs762114324, COSV67177276; called by muse, mutect2, varscan2
- PAN2 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.188); catalogued as COSV99228471; called by muse, mutect2, varscan2
- PAPPA2 | c.106G>C p.E36Q | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV62780932; called by muse, mutect2, varscan2
- PARP4 | c.4006C>T p.P1336S | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV101132009; called by muse, mutect2, varscan2
- PAX3 | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.148); catalogued as COSV51337718, COSV99286781; called by muse, mutect2, varscan2
- PCDHA1 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs782656813, COSV100974452; called by muse, mutect2, varscan2
- PCLO | c.3649G>T p.E1217* | Nonsense Mutation (SNP) | VAF 49/223 reads (22%) | catalogued as COSV100436951, COSV61651697; called by muse, mutect2, varscan2
- PCM1 | c.3766G>A p.E1256K | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.789); catalogued as COSV100279489, COSV59588595; called by muse, mutect2, varscan2
- PFKFB2 | c.1453G>T p.G485W | Missense Mutation (SNP) | VAF 26/120 reads (22%) | PolyPhen possibly damaging (0.832); catalogued as COSV100892046; called by muse, mutect2, varscan2
- PIAS2 | c.1447G>C p.D483H | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.738); catalogued as COSV100245509; called by muse, mutect2, varscan2
- PIRT | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.202); catalogued as COSV101652685; called by muse, mutect2
- PKHD1 | c.8864G>T p.R2955L | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100583436, COSV61873820; called by muse, mutect2, varscan2
- PLBD1 | c.350A>C p.H117P | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99554790; called by muse, mutect2, varscan2
- PLEC | c.7558G>A p.E2520K (on ENST00000322810 / NM_201380.4; = p.E2410K on NM_000445.5) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.108); catalogued as COSV100516041, COSV100518327; called by muse, mutect2, varscan2
- PLEKHG1 | c.4001T>A p.V1334D | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as COSV100651708; called by muse, mutect2, varscan2
- POLA1 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs766311613, COSV100985748; called by muse, mutect2, varscan2
- PRKDC | c.7274G>C p.R2425T | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.72); PolyPhen benign (0.013); catalogued as COSV100042522; called by muse, mutect2, varscan2
- RAC1 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as COSV61821605; called by muse, mutect2, varscan2
- RASAL3 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs201985806, COSV100640332; called by muse, mutect2, varscan2
- RNFT2 | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.041); catalogued as rs751624015, COSV99985512; called by muse, mutect2, varscan2
- RRP1B | c.1270G>T p.E424* | Nonsense Mutation (SNP) | VAF 9/39 reads (23%) | catalogued as COSV100513213; called by mutect2, varscan2
- RRP1B | c.1497G>C p.Q499H | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.201); catalogued as rs1157031191, COSV100513217; called by muse, mutect2, varscan2
- SCAF8 | c.3728C>T p.S1243L | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100914256; called by muse, mutect2, varscan2
- SCLT1 | c.523C>T p.H175Y | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV99828443; called by muse, mutect2, varscan2
- SCN1A | c.2313C>G p.D771E (on ENST00000303395 / NM_001202435.3; = p.D760E on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.145); catalogued as COSV100321828; called by muse, mutect2, varscan2
- SETD2 | c.7239-2A>T p.X2413_splice | Splice Site (SNP) | VAF 15/53 reads (28%) | catalogued as COSV57434559; called by muse, mutect2, varscan2
- SIN3B | c.2164G>A p.G722R | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as COSV99932002; called by muse, mutect2, varscan2
- SLC20A1 | c.1025C>A p.T342N | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV99734212; called by muse, mutect2, varscan2
- SLC8A3 | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 26/204 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1361493951, COSV63523371; called by muse, mutect2, varscan2
- SLIT1 | c.1417G>A p.A473T | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as rs371811928; called by muse, mutect2, varscan2
- SNX32 | c.442C>T p.H148Y | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV100362675; called by muse, mutect2, varscan2
- SP1 | c.1685G>C p.G562A (on ENST00000327443 / NM_138473.3; = p.G555A on NM_003109.1) | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV100540828; called by muse, mutect2, varscan2
- SPEN | c.7476G>C p.Q2492H | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated, low confidence (0.57); PolyPhen probably damaging (0.965); catalogued as rs771418115, COSV101005546; called by muse, mutect2, varscan2
- SPTAN1 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.9); catalogued as rs915429220, COSV100823966; called by muse, mutect2, varscan2
- SPTAN1 | c.6260G>T p.R2087L | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.199); catalogued as rs1301624113, COSV100823967; called by muse, mutect2, varscan2
- STIM2 | c.1054C>T p.Q352* | Nonsense Mutation (SNP) | VAF 29/102 reads (28%) | catalogued as COSV99403199; called by muse, mutect2, varscan2
- STK25 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV100346579; called by muse, mutect2, varscan2
- SYNE1 | c.6695G>A p.R2232K (on ENST00000367255 / NM_182961.4; = p.R2239K on NM_033071.3) | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV55023980; called by muse, mutect2, varscan2
- SYNJ1 | c.2491G>A p.D831N | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as COSV59157134; called by muse, mutect2
- TARDBP | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as COSV99534441; called by muse, mutect2, varscan2
- TFAP2B | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs372031178, COSV99540755; called by muse, mutect2, varscan2
- TMEM131 | c.200C>G p.S67* | Nonsense Mutation (SNP) | VAF 5/32 reads (16%) | catalogued as COSV99489386; called by muse, mutect2, varscan2
- TNKS1BP1 | c.4775del p.G1592Vfs*34 | Frame Shift Del (DEL) | VAF 26/106 reads (25%) | catalogued as rs1565037155; called by mutect2, varscan2
- TPM2 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 55/237 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.825); catalogued as COSV100253480; called by muse, mutect2, varscan2
- TRAV8-4 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778416644; called by muse, mutect2, varscan2
- TRERF1 | c.3279-1G>C p.X1093_splice | Splice Site (SNP) | VAF 86/320 reads (27%) | catalogued as COSV100551498; called by muse, mutect2, varscan2
- TTBK2 | c.2337G>C p.E779D | Missense Mutation (SNP) | VAF 63/225 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV99142356; called by muse, mutect2, varscan2
- TTF2 | c.2168C>G p.S723* | Nonsense Mutation (SNP) | VAF 25/115 reads (22%) | catalogued as COSV101037807; called by muse, mutect2, varscan2
- USP31 | c.2017C>T p.P673S | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99565778; called by muse, mutect2, varscan2
- USP4 | c.1181C>G p.S394C | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.292); catalogued as COSV55535193, COSV99649685; called by muse, mutect2, varscan2
- VSIG8 | c.712C>G p.Q238E | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as COSV100928834; called by muse, mutect2, varscan2
- ZFYVE1 | c.111C>G p.C37W | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100607055; called by muse, mutect2, varscan2
- ZNF483 | c.571C>T p.Q191* | Nonsense Mutation (SNP) | VAF 27/149 reads (18%) | catalogued as COSV100493101; called by muse, mutect2, varscan2
- ZNF484 | c.1207C>A p.Q403K | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as COSV100214841; called by muse, mutect2, varscan2
- ZNF765 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.019); catalogued as COSV101125555; called by muse, mutect2, varscan2
- ZNF846 | c.877C>T p.H293Y | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101194376; called by muse, mutect2, varscan2
- C9orf131 | c.580_581del p.Q194Afs*44 | Frame Shift Del (DEL) | VAF 18/143 reads (13%) | called by mutect2, pindel, varscan2
- FAT1 | c.6846_6847del p.F2283Cfs*11 | Frame Shift Del (DEL) | VAF 50/144 reads (35%) | called by pindel, varscan2
- GNAI1 | c.461+1_461+3del p.X154_splice | Splice Site (DEL) | VAF 6/48 reads (13%) | called by pindel, varscan2
- KMT2D | c.14366_14367del p.S4789Cfs*27 | Frame Shift Del (DEL) | VAF 25/115 reads (22%) | called by pindel, varscan2
- KRT5 | c.1218+1_1218+2dup | Splice Region (INS) | VAF 30/166 reads (18%) | called by mutect2, pindel, varscan2
- ZBED2 | c.301_336del p.H101_K112del | In Frame Del (DEL) | VAF 12/98 reads (12%) | called by mutect2, pindel
- ADAMTS20 | c.3426C>T p.T1142= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs376977266; called by muse, mutect2, varscan2
- ADAMTS7 | c.3054G>A p.E1018= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV101183233; called by muse, mutect2, varscan2
- ANGPT2 | c.1278G>A p.K426= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as COSV100291161; called by muse, mutect2, varscan2
- ASAP3 | c.141A>G p.G47= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as COSV100369631; called by muse, mutect2, varscan2
- ATP2A1 | c.2229C>T p.I743= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as COSV62871279; called by muse, mutect2, varscan2
- BAZ2A | c.4818C>T p.L1606= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV99467513; called by muse, mutect2, varscan2
- C17orf75 | c.228C>T p.S76= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as COSV99858778; called by muse, mutect2, varscan2
- CEP152 | c.1713C>A p.L571= | Silent (SNP) | VAF 34/203 reads (17%) | catalogued as COSV100359114; called by muse, mutect2, varscan2
- CERCAM | c.774C>T p.S258= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as rs369693807; called by muse, mutect2, varscan2
- CTC1 | c.414C>T p.N138= | Silent (SNP) | VAF 38/155 reads (25%) | catalogued as COSV100236731; called by muse, mutect2, varscan2
- DCAF12 | c.516G>T p.T172= | Silent (SNP) | VAF 28/155 reads (18%) | catalogued as rs775650096, COSV100778404; called by muse, mutect2, varscan2
- DDX43 | c.105G>A p.L35= | Silent (SNP) | VAF 36/133 reads (27%) | catalogued as COSV100946485, COSV64836729; called by muse, mutect2, varscan2
- DOCK9 | c.2868G>A p.L956= (on ENST00000376460 / NM_001366676.2; = p.L957= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs989634304, COSV100240796; called by muse, mutect2, varscan2
- EXOSC5 | c.246G>A p.P82= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as rs766392972, COSV54200757; called by muse, mutect2, varscan2
- FAM47A | c.1479G>A p.S493= | Silent (SNP) | VAF 26/144 reads (18%) | catalogued as COSV100650042; called by muse, varscan2
- FAM71C | c.558C>T p.I186= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV100175817; called by muse, mutect2, varscan2
- FEZ1 | c.69G>A p.P23= | Silent (SNP) | VAF 27/122 reads (22%) | catalogued as rs575776265, COSV99631081; called by muse, mutect2, varscan2
- FKTN | c.804G>A p.V268= | Silent (SNP) | VAF 19/136 reads (14%) | catalogued as COSV99795572; called by muse, mutect2, varscan2
- FLG | c.11583C>T p.S3861= | Silent (SNP) | VAF 55/314 reads (18%) | catalogued as rs1324821560, COSV100912050; called by muse, mutect2, varscan2
- HLA-A | c.387G>C p.S129= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as rs45505094, COSV100954659; called by muse, varscan2
- HPS5 | c.1047C>G p.V349= (on ENST00000349215 / NM_181507.2; = p.V235= on NM_007216.4) | Silent (SNP) | VAF 15/136 reads (11%) | catalogued as COSV100752359; called by muse, mutect2, varscan2
- HRH3 | c.120C>T p.L40= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs1178839727, COSV100420705; called by muse, mutect2, varscan2
- HSPA2 | c.165C>T p.A55= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as rs763199500, COSV99904995; called by muse, mutect2, varscan2
- LRRIQ4 | c.351C>T p.L117= | Silent (SNP) | VAF 18/107 reads (17%) | catalogued as COSV100540364; called by muse, mutect2, varscan2
- MAP3K13 | c.1569C>T p.I523= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as COSV99407815; called by muse, mutect2, varscan2
- MGA | c.2721C>T p.F907= | Silent (SNP) | VAF 23/185 reads (12%) | catalogued as COSV99581339; called by muse, mutect2, varscan2
- MID1 | c.1065C>T p.L355= | Silent (SNP) | VAF 13/94 reads (14%) | catalogued as COSV100452686; called by muse, mutect2, varscan2
- MMP14 | c.669C>G p.V223= | Silent (SNP) | VAF 9/98 reads (9%) | catalogued as COSV100314299; called by muse, mutect2
- MSTN | c.765C>T p.V255= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV99640817; called by muse, mutect2, varscan2
- MTHFSD | c.474C>T p.A158= (on ENST00000360900 / NM_001159377.2; = p.A157= on NM_022764.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs200844727; called by muse, mutect2, varscan2
- NIP7 | c.189G>A p.L63= | Silent (SNP) | VAF 22/108 reads (20%) | catalogued as rs918690068, COSV99650884; called by muse, mutect2, varscan2
- NLRP12 | c.762G>A p.E254= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV100145785; called by muse, mutect2, varscan2
- NRCAM | c.3555G>A p.L1185= (on ENST00000379028 / NM_001371124.1; = p.L1064= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as COSV100695358; called by muse, mutect2, varscan2
- NUP93 | c.1770C>T p.D590= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as rs774171293, COSV57430484; called by muse, mutect2, varscan2
- PAPOLB | c.141C>G p.L47= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs774800091, COSV101271312, COSV101271608; called by muse, mutect2, varscan2
- PCDHA8 | c.1614C>T p.R538= | Silent (SNP) | VAF 44/222 reads (20%) | catalogued as rs1329962165, COSV65323304; called by muse, mutect2, varscan2
- PGAM4 | c.114G>A p.A38= | Silent (SNP) | VAF 63/250 reads (25%) | catalogued as rs1171951930, COSV100431562; called by muse, mutect2, varscan2
- PGAP4 | c.1155G>A p.V385= | Silent (SNP) | VAF 21/91 reads (23%) | catalogued as COSV66388222; called by muse, mutect2, varscan2
- PGBD5 | c.390C>T p.L130= (on ENST00000525115; = p.L199= on NM_001258311.2) | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as rs763962591, COSV100358719; called by muse, mutect2, varscan2
- PTCHD3 | c.846C>T p.S282= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV101438961; called by muse, mutect2, varscan2
- RAB12 | c.642G>A p.R214= | Silent (SNP) | VAF 9/96 reads (9%) | catalogued as COSV100251667; called by muse, mutect2, varscan2
- SH3KBP1 | c.1707G>A p.A569= | Silent (SNP) | VAF 7/73 reads (10%) | catalogued as rs746570736, COSV101116382; called by muse, mutect2
- SLCO1B1 | c.1782G>C p.L594= | Silent (SNP) | VAF 18/200 reads (9%) | catalogued as COSV99919025; called by muse, mutect2
- TLE5 | c.411C>G p.A137= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV99682356; called by muse, varscan2
- TLE5 | c.394C>T p.L132= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs916325537, COSV99682357; called by muse, varscan2
- TRHDE | c.1779C>A p.L593= | Silent (SNP) | VAF 62/272 reads (23%) | catalogued as COSV99672234; called by muse, mutect2, varscan2
- TROAP | c.2133G>A p.L711= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as COSV57746058; called by muse, mutect2, varscan2
- TRPM4 | c.2835C>T p.G945= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as COSV53268607; called by muse, mutect2, varscan2
- TSC2 | c.4602C>T p.L1534= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs368534883; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- UPF3B | c.1314G>A p.A438= (on ENST00000276201 / NM_080632.3; = p.A425= on NM_023010.3) | Silent (SNP) | VAF 14/158 reads (9%) | catalogued as rs149544140, COSV99352356; called by muse, mutect2
- VPS13B | c.11787G>A p.Q3929= | Silent (SNP) | VAF 127/348 reads (36%) | catalogued as rs1185762932, COSV100663351, COSV62150607; called by muse, mutect2, varscan2
- ZMIZ1 | c.840G>A p.A280= | Silent (SNP) | VAF 31/127 reads (24%) | catalogued as rs375414407; called by muse, mutect2, varscan2
- ZNF222 | c.562C>T p.L188= | Silent (SNP) | VAF 40/189 reads (21%) | catalogued as COSV99496581; called by muse, mutect2, varscan2
- JPH2 | c.379+8367dup | Intron (INS) | VAF 20/126 reads (16%) | called by mutect2, pindel, varscan2
- MIR147A | n.54G>A | RNA (SNP) | VAF 38/169 reads (22%) | called by muse, mutect2, varscan2
- RCC1 | c.-228-76G>A | Intron (SNP) | VAF 21/84 reads (25%) | catalogued as COSV100775662; called by muse, mutect2, varscan2
- SLC22A20P | n.1413G>A | RNA (SNP) | VAF 16/78 reads (21%) | called by muse, varscan2
